Gene-level copy-number profile of tumor specimen C3L-00080-01 from CPTAC case C3L-00080, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 58.0 years (21,194 days).
Specimen C3L-00080-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e918c908-4f37-4f9b-aacb-c90434220aa3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-00080-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/a0c36a46-e207-4767-82c5-b760ecbb1b39

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 532; copy number 1: 2,107; copy number 2: 18,561; copy number 3: 13,760; copy number 4: 14,535; copy number 5: 4,920; copy number 6: 3,011; copy number 7: 1,003; copy number 8: 144; copy number 9: 30; copy number 10: 12; copy number 11: 39; copy number 14: 95; copy number 19: 24; copy number 20: 28; copy number 21: 65; copy number 22: 11; copy number 59: 4; copy number 78: 30.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,502,145–49,589,529, 11 genes: ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr12:11,351,823–11,395,566, 1 gene (within-gene range 0–2): PRB1.
- chr17:18,426,861–18,506,313, 8 genes: KRT17P2, KRT16P1, KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 9,408 genes in 43 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–156,192,203, 580 genes, copy number 5–8 (broad region; genes not listed).
- chr1:160,151,586–163,423,164, 125 genes, copy number 7–14 (broad region; genes not listed).
- chr2:26,190,635–53,970,993, 452 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr2:54,456,317–55,500,055, 24 genes, copy number 6–7: SPTBN1, SPTBN1-AS1, RPL23AP32, AC092839.1, AC093110.1, EML6, EML6-AS1, AC104781.1, RNU7-81P, RTN4, RNU6-433P, CLHC1, AC012358.1, CDPF1P1, RPS27A, MTIF2, PRORSD1P, AC012358.2, Y_RNA, CCDC88A, BTF3P5, RNU6-775P, RNU6-221P, RNU6-634P.
- chr2:59,014,354–63,046,487, 80 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr2:64,817,378–80,648,861, 301 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr2:81,967,079–82,609,977, 7 genes, copy number 5: RN7SL201P, AC079896.1, LYARP1, RNU6-685P, Y_RNA, AC010105.1, RBX1P1.
- chr2:85,561,562–89,907,246, 146 genes, copy number 5 (broad region; genes not listed).
- chr3:93,843,764–198,123,232, 1,753 genes, copy number 5 (broad region; genes not listed).
- chr4:51,843,000–59,834,167, 137 genes, copy number 5–10 (broad region; genes not listed).
- chr5:58,198–11,904,446, 233 genes, copy number 7 (broad region; genes not listed).
- chr5:144,856,890–149,432,835, 82 genes, copy number 5 (broad region; genes not listed).
- chr5:150,485,818–169,604,778, 243 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr6:134,074,123–144,853,034, 169 genes, copy number 5 (broad region; genes not listed).
- chr7:15,611,212–17,680,659, 34 genes, copy number 5: MEOX2, AC005550.2, LINC02587, AC005550.1, RPL36AP26, AC006041.1, CRPPA, RPL36AP29, CRPPA-AS1, SOSTDC1, AC005014.3, LRRC72, AC005014.1, AC005014.2, ANKMY2, AC005014.4, BZW2, AC073333.1, TSPAN13, AGR2, AC073333.2, AGR3, RAD17P1, AC098592.2, AHR, AC098592.1, AC073332.1, BRWD1P3, Metazoa_SRP, AC019117.3, SNORA63, AC019117.2, AC019117.1, AC006482.1.
- chr8:137,809,444–143,878,467, 135 genes, copy number 5 (broad region; genes not listed).
- chr10:47,300,197–48,672,424, 38 genes, copy number 5: GDF10, GDF2, RBP3, ZNF488, ANXA8, AL591684.3, FAM25G, AL591684.1, AGAP9, AL591684.2, RNA5SP312, BMS1P2, BX547991.1, DUSP8P1, CTSLP2, LINC02675, SHLD2P3, RN7SL453P, RHEBP2, FO681492.1, AC245041.2, NPY4R2, AC245041.1, FAM25C, AGAP12P, RNA5SP315, BMS1P7, PTPN20CP, FRMPD2, AC074325.1, RPS6P14, MAPK8, AC016397.2, ARHGAP22, ARHGAP22-IT1, AC016397.1, AC068898.2, AC068898.1.
- chr10:53,802,771–55,627,942, 1 gene, copy number 5 (within-gene range 4–5): PCDH15.
- chr10:54,486,230–55,746,908, 10 genes, copy number 5: AL353784.1, NEFMP1, MIR548F1, AC051618.1, AC016822.1, AL355314.1, AL355314.2, MTRNR2L5, GAPDHP21, AC069545.1.
- chr10:121,478,332–121,739,730, 4 genes, copy number 6: FGFR2, AC009988.1, RPS15AP5, AC025947.1.
- chr11:63,838,928–69,704,022, 326 genes, copy number 5–6 (broad region; genes not listed).
- chr11:70,270,690–71,252,577, 19 genes, copy number 5 (within-gene range 5–9): PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1.
- chr11:130,314,993–131,004,429, 12 genes, copy number 5: ZBTB44-DT, ADAMTS8, ADAMTS15, AP004371.1, BAK1P2, MIR8052, LINC02873, PPP1R10P1, LINC02551, SNX19, AP003486.1, RN7SL167P.
- chr11:131,253,422–131,350,917, 1 gene, copy number 6: AP002856.2.
- chr12:57,693,955–76,615,567, 337 genes, copy number 7–14 (broad region; genes not listed).
- chr12:76,721,534–76,757,914, 2 genes, copy number 5: RPL7P43, AC093014.1.
- chr12:76,984,079–118,145,584, 686 genes, copy number 5–6 (broad region; genes not listed).
- chr14:19,664,098–106,879,812, 2,190 genes, copy number 6–7 (within-gene range 3–7) (broad region; genes not listed).
- chr16:49,066,567–52,677,747, 85 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr17:3,276,942–4,898,061, 77 genes, copy number 6–10 (within-gene range 4–10) (broad region; genes not listed).
- chr17:36,183,235–36,334,759, 10 genes, copy number 7: AC243829.1, CCL3L3, CCL4L2, AC243829.5, AC243829.3, AC243829.6, TBC1D3I, AC233699.1, Y_RNA, TBC1D3G.
- chr17:37,642,947–46,886,730, 494 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr18:7,995,570–10,626,353, 61 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr18:10,666,483–15,330,282, 149 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr18:24,932,771–26,193,355, 13 genes, copy number 8–14: LINC01894, WBP2P1, AC104961.1, ZNF521, AC105114.2, AC105114.1, AC110603.1, RN7SL97P, AC027229.1, SS18, RPS24P18, PSMA8, DHFRP1.
- chr18:27,932,879–46,463,140, 194 genes, copy number 7–78 (broad region; genes not listed).
- chr19:27,638,483–28,125,430, 15 genes, copy number 5: ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1.
- chr19:56,219,670–57,066,139, 43 genes, copy number 6: ZSCAN5A, ZSCAN5DP, EDDM13, AC006116.5, AC006116.7, Y_RNA, VN2R17P, AC006116.1, AC006116.3, AC006116.2, AC006116.6, AC006116.8, ZNF542P, ZNF582, AC006116.9, SLC25A36P1, AC006116.4, ZNF582-AS1, ZNF583, ZNF667, ZNF667-AS1, AC004696.2, AC004696.1, ZNF471, AC005498.1, AC005498.2, ZFP28, AC005498.3, ZNF470, SIGLEC31P, ZNF71, ZIM2-AS1, SMIM17, ZNF835, AC006115.2, OR5AH1P, ZIM2, AC006115.1, PEG3, MIMT1, AC004792.1, AC044792.1, RPL7AP69.
- chr19:57,389,850–58,481,230, 95 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr21:18,561,265–22,884,000, 42 genes, copy number 5: MIR548XHG, AF240627.1, MIR548X, PPIAP22, AL157359.3, AL157359.2, AL157359.1, AP000431.2, AP000431.1, SLC6A6P1, AP000855.1, RNU1-139P, RPL37P4, NIPA2P3, SREK1IP1P1, C1QBPP1, LINC01683, LINC02573, RNU6-772P, RN7SKP147, FDPSP6, KRT18P2, RPS3AP1, AP001506.1, LINC00320, PPIAP1, NCAM2, AP001136.1, AP001117.1, AF241725.1, LINC00317, LINC01425, AP000472.1, LINC01687, LINC00308, AP000705.2, AP000705.1, RNU4-45P, AP000561.1, MAPK6P2, AP000959.1, AP000949.1.

Autosomal genes at a single copy (total copy number 1): 1,175. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
